Somatic mutation profile of tumor specimen TCGA-LN-A8I0-01A (aliquot TCGA-LN-A8I0-01A-11D-A36J-09) from TCGA case TCGA-LN-A8I0, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 52.9 years (19,328 days).
Specimen TCGA-LN-A8I0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec3ec82e-4765-492d-9c38-16443c75fb1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A8I0-10A (Blood Derived Normal), aliquot TCGA-LN-A8I0-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23fd83ee-fee6-4b90-bbe3-d5a7e5549135

The open-access MAF lists 57 somatic variants for this specimen: 37 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 17, Frame Shift Del 2, 5'UTR 1, Nonsense Mutation 1, RNA 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553487942, COSV67960075, COSV67960449, COSV67960680; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- ACTB | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.399); catalogued as COSV59317815; called by muse, mutect2, varscan2
- BANK1 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); catalogued as COSV100535571, COSV59850236; called by muse, mutect2, varscan2
- COL18A1 | c.1982G>T p.G661V (on ENST00000359759 / NM_130444.3; = p.G426V on NM_030582.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.145); catalogued as COSV62703015; called by muse, mutect2, varscan2
- DLGAP3 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as rs777705397, COSV52394406; called by muse, mutect2, varscan2
- FAM155A | c.800C>G p.A267G | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65553108; called by muse, mutect2, varscan2
- GJA8 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV53787689; called by muse, mutect2, varscan2
- KBTBD4 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs372890651; called by muse, mutect2, varscan2
- L3MBTL4 | c.803A>T p.N268I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs139480207; called by muse, mutect2, varscan2
- MVP | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs769471740; called by muse, mutect2, varscan2
- MYH6 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs760632098; called by muse, mutect2, varscan2
- MYPN | c.2464C>T p.R822W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs529221329, COSV100589576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAV2 | c.3814A>G p.T1272A (on ENST00000396087 / NM_001244963.2; = p.T1249A on NM_145117.5) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60663679; called by muse, mutect2, varscan2
- POGZ | c.845C>T p.T282M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.247); catalogued as rs1046095442; called by muse, mutect2, varscan2
- PSD2 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV51210114, COSV99216993; called by muse, mutect2, varscan2
- PSG4 | c.1167T>A p.S389R | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs143496527, COSV54939170; called by muse, mutect2, varscan2
- RTN2 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV55593161; called by muse, mutect2, varscan2
- STAB2 | c.2239C>A p.P747T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV101186171; called by muse, mutect2, varscan2
- TMEM134 | c.317_319del p.N106del | In Frame Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs1458662134; called by pindel, varscan2
- TSPAN6 | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV100885835, COSV65957581; called by muse, mutect2, varscan2
- TSSC4 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs778974704; called by muse, mutect2, varscan2
- ACSL3 | c.1380G>T p.Q460H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- ADAM18 | c.244C>A p.H82N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AOX1 | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ARHGEF16 | c.1040A>T p.E347V | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- HRC | c.1531C>T p.H511Y | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- IARS1 | c.2759G>A p.S920N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2
- KLK11 | c.30del p.W10* | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- MTTP | c.2220A>T p.E740D | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6K6 | c.622G>A p.D208N (on ENST00000368144; = p.D184N on NM_001005184.1) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSTF1 | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2
- PAPPA2 | c.2154C>A p.S718R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RYR2 | c.3846_3861del p.C1282* | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- SEMA3D | c.1506C>A p.H502Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TP53BP2 | c.3093C>A p.D1031E (on ENST00000343537 / NM_001031685.3; = p.D902E on NM_005426.2) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- YY1 | c.1130A>G p.H377R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ACACB | c.4656C>T p.I1552= | Silent (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- AHCYL2 | c.1248C>T p.S416= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV61490064; called by muse, mutect2, varscan2
- CLPTM1L | c.336C>T p.H112= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs762040634; called by muse, mutect2, varscan2
- CWF19L1 | c.297A>G p.K99= | Silent (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- DSC2 | c.1119C>A p.I373= | Silent (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- EIF2A | c.975T>C p.H325= | Silent (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- ERCC3 | c.1680C>A p.V560= | Silent (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- GPC6 | c.642C>A p.A214= | Silent (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- NOTCH4 | c.1950C>G p.L650= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- OR52W1 | c.441T>C p.G147= | Silent (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- OR5R1 | c.159T>G p.T53= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- OR8H1 | c.459C>T p.I153= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- PTGS1 | c.663G>A p.K221= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs1357605941; called by muse, mutect2, varscan2
- SPNS2 | c.900C>T p.T300= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1456180582; called by muse, mutect2, varscan2
- TBR1 | c.1818C>T p.P606= | Silent (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- TLN1 | c.4860C>T p.L1620= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs554877602; called by muse, mutect2, varscan2
- ZNF99 | c.1653C>A p.T551= | Silent (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850968 C>T | 3'Flank (SNP) | VAF 15/21 reads (71%) | called by muse, mutect2, varscan2
- OR52A4P | n.911C>T | RNA (SNP) | VAF 9/31 reads (29%) | catalogued as rs770430743; called by muse, mutect2, varscan2
- PHACTR4 | c.-95_-64delinsT | 5'UTR (DEL) | VAF 61/116 reads (53%) | called by pindel, varscan2*
